Somatic mutation profile of tumor specimen C3L-01869-02 (aliquot CPT0104250009) from CPTAC case C3L-01869, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 54.9 years (20,066 days).
Specimen C3L-01869-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 484b45d6-7a12-44eb-875e-5580d32fbbfc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01869-31 (Blood Derived Normal), aliquot CPT0105100002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ae34d2c-98bf-4fe0-9bec-8ee4f08ea364

The open-access MAF lists 69 somatic variants for this specimen: 42 protein-altering or splice-affecting, 14 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, Silent 14, Intron 6, Frame Shift Del 4, 3'UTR 2, RNA 2, 5'Flank 2, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ARMC4 | c.158T>C p.F53S | Missense Mutation (SNP) | VAF 26/289 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1468048392; called by muse, mutect2
- CCBE1 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 28/537 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.609); catalogued as rs147208835; ClinVar: uncertain significance; called by muse, mutect2
- COQ6 | c.287C>T p.T96M | Missense Mutation (SNP) | VAF 142/517 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.27); catalogued as rs372647932; called by muse, varscan2
- CTNNA2 | c.1612C>T p.R538W | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs751754914, COSV100559548; called by muse, mutect2, varscan2
- ESCO2 | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 86/473 reads (18%) | SIFT tolerated (0.07); PolyPhen benign (0.293); catalogued as COSV59413224; called by muse, mutect2, varscan2
- MAN2C1 | c.1112C>T p.P371L | Missense Mutation (SNP) | VAF 83/248 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs747470535, COSV104389852; called by muse, mutect2, varscan2
- PCDHB12 | c.182C>T p.S61L | Missense Mutation (SNP) | VAF 42/149 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV53394680; called by muse, mutect2, varscan2
- RNF34 | c.705A>T p.E235D | Missense Mutation (SNP) | VAF 40/195 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs61751317; called by muse, mutect2, varscan2
- SETD2 | c.4584del p.E1528Dfs*37 | Frame Shift Del (DEL) | VAF 38/123 reads (31%) | catalogued as COSV57437860; called by mutect2, pindel, varscan2
- TMEM158 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); catalogued as rs1412098237; called by muse, mutect2, varscan2
- ZNF500 | c.1313C>T p.T438I | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.025); catalogued as rs1199480954; called by muse, mutect2, varscan2
- AKAP1 | c.2695T>G p.Y899D | Missense Mutation (SNP) | VAF 107/261 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.536); called by muse, mutect2, varscan2
- ANKRD18B | c.1414del p.S472Lfs*3 | Frame Shift Del (DEL) | VAF 49/165 reads (30%) | called by mutect2, pindel, varscan2
- ARHGEF9 | c.766C>A p.L256I | Missense Mutation (SNP) | VAF 18/450 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- BRD1 | c.3091G>A p.A1031T (on ENST00000216267 / NM_001349940.1; = p.A1162T on NM_001304808.3) | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.235); called by muse, mutect2, varscan2
- CASD1 | c.1541T>G p.F514C | Missense Mutation (SNP) | VAF 46/164 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, varscan2
- DDX60 | c.3332T>A p.I1111N | Missense Mutation (SNP) | VAF 99/354 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ECPAS | c.877A>G p.I293V | Missense Mutation (SNP) | VAF 99/348 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBLIM1 | c.80C>A p.A27E | Missense Mutation (SNP) | VAF 105/361 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- HUWE1 | c.7862A>G p.D2621G | Missense Mutation (SNP) | VAF 165/486 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- KLHL18 | c.44del p.F15Sfs*26 | Frame Shift Del (DEL) | VAF 56/169 reads (33%) | called by mutect2, pindel, varscan2
- KPNA4 | c.404C>G p.A135G | Missense Mutation (SNP) | VAF 39/246 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- LMNB1 | c.960G>T p.R320S | Missense Mutation (SNP) | VAF 83/231 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.349); called by muse, mutect2, varscan2
- LOXL1 | c.205T>C p.S69P | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT tolerated (0.56); PolyPhen benign (0); called by muse, mutect2, varscan2
- LTA | c.382C>A p.P128T | Missense Mutation (SNP) | VAF 18/273 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.353); called by muse, mutect2
- MBP | c.534C>A p.F178L (on ENST00000355994 / NM_001025101.2; = p.F45L on NM_002385.3) | Missense Mutation (SNP) | VAF 25/270 reads (9%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.977); called by muse, mutect2
- NADSYN1 | c.127G>A p.G43R | Missense Mutation (SNP) | VAF 38/204 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBPF11 | c.2360A>C p.D787A | Missense Mutation (SNP) | VAF 192/366 reads (52%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.822); called by muse, mutect2, varscan2
- NEURL1 | c.1682G>A p.R561H | Missense Mutation (SNP) | VAF 93/247 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NRTN | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 45/146 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR5M10 | c.650C>T p.S217F | Missense Mutation (SNP) | VAF 103/386 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.651); called by muse, mutect2, varscan2
- PEX11G | c.277T>A p.S93T | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.455); called by muse, mutect2, varscan2
- SEMA3F | c.713G>T p.G238V | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2
- TNFRSF1A | c.555T>A p.C185* | Nonsense Mutation (SNP) | VAF 108/454 reads (24%) | called by muse, mutect2, varscan2
- TOP3A | c.1678C>G p.L560V | Missense Mutation (SNP) | VAF 56/217 reads (26%) | SIFT tolerated (0.78); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TRIM51GP | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 22/416 reads (5%) | called by muse, mutect2
- TRIOBP | c.6824A>G p.N2275S (on ENST00000644935 / NM_001039141.3; = p.N562S on NM_007032.5) | Missense Mutation (SNP) | VAF 25/612 reads (4%) | SIFT tolerated (0.83); PolyPhen benign (0.001); called by muse, mutect2
- TRIP6 | c.976G>A p.A326T | Missense Mutation (SNP) | VAF 36/106 reads (34%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- TRMT11 | c.1156G>A p.V386M | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.317); called by muse, mutect2, varscan2
- VHL | c.369del p.T124Hfs*35 | Frame Shift Del (DEL) | VAF 136/375 reads (36%) | called by mutect2, pindel, varscan2
- WBP11 | c.1319C>T p.P440L | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZNF573 | c.1415G>T p.C472F (on ENST00000536220 / NM_001172692.1; = p.C414F on NM_152360.3) | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ACAD10 | c.3003G>A p.P1001= | Silent (SNP) | VAF 22/290 reads (8%) | catalogued as rs750301886, COSV58163033; called by muse, mutect2
- ANO2 | c.2862C>G p.L954= (on ENST00000356134 / NM_001278597.3; = p.L958= on NM_001278596.3) | Silent (SNP) | VAF 26/392 reads (7%) | called by muse, mutect2
- CABIN1 | c.4425C>T p.P1475= | Silent (SNP) | VAF 112/363 reads (31%) | catalogued as rs1427588194; called by muse, mutect2, varscan2
- CAPN12 | c.1308G>A p.R436= | Silent (SNP) | VAF 68/271 reads (25%) | catalogued as rs1225580005; called by muse, mutect2, varscan2
- COG1 | c.2493G>A p.R831= | Silent (SNP) | VAF 30/724 reads (4%) | catalogued as rs1022530525; called by muse, mutect2
- CRMP1 | c.445C>A p.R149= | Silent (SNP) | VAF 59/201 reads (29%) | called by muse, mutect2, varscan2
- FAT3 | c.5829C>T p.N1943= | Silent (SNP) | VAF 24/418 reads (6%) | catalogued as rs779339214; called by muse, mutect2
- FBXO44 | c.288G>A p.L96= | Silent (SNP) | VAF 67/283 reads (24%) | called by muse, mutect2, varscan2
- HIPK3 | c.3570T>C p.H1190= | Silent (SNP) | VAF 140/426 reads (33%) | called by muse, mutect2, varscan2
- OR51G1 | c.843G>A p.V281= | Silent (SNP) | VAF 49/180 reads (27%) | called by muse, mutect2, varscan2
- PEAK1 | c.135T>C p.T45= | Silent (SNP) | VAF 10/202 reads (5%) | called by muse, mutect2
- SMC1B | c.523T>C p.L175= | Silent (SNP) | VAF 123/403 reads (31%) | called by muse, mutect2, varscan2
- SORL1 | c.3609C>T p.N1203= | Silent (SNP) | VAF 44/159 reads (28%) | catalogued as rs749525632, COSV99493111; called by muse, mutect2, varscan2
- SPINT1 | c.1260C>T p.T420= (on ENST00000344051 / NM_181642.3; = p.T404= on NM_003710.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 51/253 reads (20%) | catalogued as COSV100689170; called by muse, mutect2, varscan2
- AC068587.4 | n.683+5018C>A | Intron (SNP) | VAF 64/578 reads (11%) | called by muse, varscan2
- DHDDS | c.*28C>G | 3'UTR (SNP) | VAF 80/343 reads (23%) | called by muse, mutect2, varscan2
- GBA3 | c.59-8525T>A | Intron (SNP) | VAF 109/376 reads (29%) | called by muse, mutect2, varscan2
- LINC01460 | n.762A>T | RNA (SNP) | VAF 52/205 reads (25%) | called by muse, mutect2, varscan2
- MINPP1 | c.638-123A>G | Intron (SNP) | VAF 91/328 reads (28%) | called by muse, mutect2, varscan2
- MIRLET7A3 | chr22:46109335 T>C | 5'Flank (SNP) | VAF 49/175 reads (28%) | called by muse, mutect2, varscan2
- NADK | c.394-262G>C | Intron (SNP) | VAF 77/360 reads (21%) | catalogued as rs559271234, COSV100410635; called by muse, mutect2, varscan2
- OR10D1P | n.66G>T | RNA (SNP) | VAF 79/304 reads (26%) | called by muse, varscan2
- PNP | c.181+46G>T | Intron (SNP) | VAF 120/380 reads (32%) | called by muse, mutect2, varscan2
- PTPRK | c.495+229A>T | Intron (SNP) | VAF 95/357 reads (27%) | called by muse, mutect2, varscan2
- RAD54B | c.*48_*49del | 3'UTR (DEL) | VAF 33/148 reads (22%) | called by mutect2, pindel, varscan2
- TLX2 | c.-25C>T | 5'UTR (SNP) | VAF 88/290 reads (30%) | catalogued as COSV99283782; called by muse, mutect2, varscan2
- WT1 | chr11:32439435 G>A | 5'Flank (SNP) | VAF 84/422 reads (20%) | catalogued as rs1277996085; called by muse, varscan2
